Somatic mutation profile of tumor specimen 0DVPNM from CCDI case PBCMUX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,732 days).
Specimen 0DVPNM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca36137-24f4-47d4-98f2-d89e9851c46b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVPP6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f1bc7de-0aca-4198-83b0-ca4748629bba

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC16 | c.23771C>T p.T7924M | Missense Mutation (SNP) | VAF 147/362 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as rs201509856; called by muse, mutect2, varscan2
- PDGFRA | c.1153A>T p.K385* | Nonsense Mutation (SNP) | VAF 271/672 reads (40%) | catalogued as COSV57275352; called by muse, mutect2, varscan2
- PDGFRA | c.1154A>T p.K385M | Missense Mutation (SNP) | VAF 274/682 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57264818; called by muse, mutect2, varscan2
- PMS1 | c.1624A>C p.N542H | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2
- TSPYL1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 257/667 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- OR6N1 | c.360C>T p.Y120= | Silent (SNP) | VAF 199/607 reads (33%) | catalogued as rs374981578; called by muse, mutect2, varscan2
- PPCDC | c.-61C>T | 5'UTR (SNP) | VAF 121/346 reads (35%) | catalogued as rs547795550; called by muse, mutect2, varscan2
